Gene-level copy-number profile of tumor specimen TCGA-C5-A7UH-01A from TCGA case TCGA-C5-A7UH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 55.3 years (20,189 days).
Specimen TCGA-C5-A7UH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.70cb3af5-ae67-4196-88b3-1b9112601052.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A7UH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40271cbb-a180-449e-90fb-71e3beb4ff62

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 3; copy number 2: 8,664; copy number 3: 17,607; copy number 4: 18,874; copy number 5: 10,700; copy number 6: 1,163; copy number 7: 509; copy number 8: 1,467; copy number 9: 122; copy number 10: 11; copy number 11: 446; copy number 14: 249; copy number 37: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A7UH-01A-11D-A350-01): tumor purity 0.58, ploidy 3.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 829 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:193,276,668–201,229,406, 122 genes, copy number 9 (broad region; genes not listed).
- chr5:58,198–44,066,731, 695 genes, copy number 11–14 (broad region; genes not listed).
- chr16:78,495,926–78,506,568, 1 gene, copy number 37: AC046158.1.
- chr22:31,753,867–31,956,243, 2 genes, copy number 10 (within-gene range 5–10): DEPDC5, Z82190.2.
- chr22:31,816,379–32,039,896, 9 genes, copy number 10: AL022331.1, RNU6-201P, Z82190.1, C22orf24, YWHAH, AL008719.1, LINC02558, RN7SL305P, Z74021.1.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
